TCGA case TCGA-L5-A8NV — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c6ae1d70-a6a2-4a46-b67a-d1bff73a1709

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 1,599 days (4.4 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 75.4 years (27,546 days); Year of diagnosis: 2001; Method of diagnosis: Biopsy; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Cancer detection method: Symptomatic; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 78.8 years (28,798 days); Days to diagnosis: 1,252 days (3.4 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 1,252 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,252 days (3.4 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,599 days (4.4 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: Medically Treated; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 183 cm; BMI: 24.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1971.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-L5-A8NV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-L5-A8NV-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-L5-A8NV-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-L5-A8NV-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: michigan; Cancer procurement city: ann arbor; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 3; Alcohol history documented: No; History reflux disease indicator: Yes; History barretts esophageal indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,599 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,599 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,252 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-L5-A8NV-01A-11D-A37B-01): tumor purity 0.41, ploidy 3.13, whole-genome doublings 1.
